Somatic mutation profile of tumor specimen 0DH3LH from CCDI case PBBTKZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.4 years (5,974 days).
Specimen 0DH3LH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ae1a49a-9d83-4735-ae6a-826eb99790d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH3KD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82c82435-fc2c-477b-808a-b86587ba9d67

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJB4 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758277948; called by muse, mutect2, varscan2
- OLFM4 | c.401T>A p.L134Q | Missense Mutation (SNP) | VAF 32/926 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- PANK1 | c.1752C>T p.A584= (on ENST00000307534 / NM_148977.2; = p.A300= on NM_138316.4) | Silent (SNP) | VAF 191/665 reads (29%) | catalogued as rs771402120; called by muse, mutect2, varscan2
- PAPOLB | c.1737G>A p.Q579= | Silent (SNP) | VAF 35/1146 reads (3%) | called by muse, mutect2
- PAFAH1B2 | chr11:117171736 G>A | 3'Flank (SNP) | VAF 41/733 reads (6%) | catalogued as COSV59167374; called by muse, mutect2
- SLC22A8 | c.*47C>T | 3'UTR (SNP) | VAF 16/288 reads (6%) | called by muse, mutect2
